Somatic mutation profile of cancer-model specimen HCM-BROD-0476-C56-85M (3D Organoid, passage 13; aliquot HCM-BROD-0476-C56-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-BROD-0476-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 43.8 years (16,008 days).
Specimen HCM-BROD-0476-C56-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5211088-7d86-46c2-b11c-dbe312cf336a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0476-C56-10A (Blood Derived Normal), aliquot HCM-BROD-0476-C56-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11fd285b-3ab1-443c-b553-426f2a7d3f92

The open-access MAF lists 41 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 6, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGPAT3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369874117; called by muse, varscan2
- BAHCC1 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 96/454 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs566509890, COSV57022241; called by muse, varscan2
- BTLA | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1440648026; called by muse, mutect2, varscan2
- CCKBR | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1171410975; called by muse, mutect2, varscan2
- CLPP | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1185519392; called by muse, mutect2, varscan2
- CNTNAP1 | c.2812G>A p.G938R | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs905697967, COSV52849634; called by muse, mutect2, varscan2
- ITLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs912358230, COSV63537517; called by muse, mutect2, varscan2
- NUDT5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as rs775016452, COSV66718900; called by muse, mutect2, varscan2
- PAX7 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1473016979, COSV64750307; called by muse, mutect2, varscan2
- PCDHGB6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1477022032, COSV53961691; called by muse, mutect2, varscan2
- RASAL2 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.82); catalogued as rs769434802, COSV100862420; called by muse, mutect2, varscan2
- SGCD | c.752C>T p.T251M (on ENST00000435422 / NM_001128209.2; = p.T252M on NM_000337.5) | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs199520526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNED1 | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs370559891; called by muse, mutect2, varscan2
- TMEM236 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554836379; called by muse, mutect2, varscan2
- TTLL7 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1345161586, COSV53083600; called by muse, mutect2, varscan2
- USP22 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54946510; called by muse, mutect2, varscan2
- WIPF3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.972); catalogued as rs560277073; called by muse, mutect2, varscan2
- ZNF616 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1247133386; called by muse, mutect2, varscan2
- ZNF676 | c.806C>T p.S269F (on ENST00000650058; = p.S237F on NM_001001411.3) | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as COSV68092231; called by muse, mutect2, varscan2
- ABCC9 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- AGO2 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 17/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- BUB1B | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CASZ1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 26/614 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EOMES | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 34/828 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- KANK1 | c.889_893dup p.Q300Kfs*8 | Frame Shift Ins (INS) | VAF 58/148 reads (39%) | called by mutect2, varscan2
- KMT2B | c.4538C>T p.P1513L | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PRSS56 | c.1515T>A p.F505L | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RENBP | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 24/852 reads (3%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- SNRNP35 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 127/347 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TENM1 | c.5632G>A p.D1878N | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIM25 | c.548A>T p.H183L | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC93B1 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2
- ZDBF2 | c.4255C>T p.Q1419* | Nonsense Mutation (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- ASCL2 | c.543C>T p.R181= | Silent (SNP) | VAF 78/407 reads (19%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.1032G>C p.G344= | Silent (SNP) | VAF 36/228 reads (16%) | catalogued as COSV54393717; called by muse, mutect2, varscan2
- MYH7 | c.1017G>A p.L339= | Silent (SNP) | VAF 75/255 reads (29%) | called by muse, mutect2, varscan2
- OR4N2 | c.780C>T p.R260= | Silent (SNP) | VAF 77/344 reads (22%) | catalogued as rs753896543; called by muse, mutect2, varscan2
- TAMM41 | c.432C>T p.N144= | Silent (SNP) | VAF 97/293 reads (33%) | catalogued as rs144979072; called by muse, mutect2, varscan2
- TTYH3 | c.1314C>T p.L438= | Silent (SNP) | VAF 28/678 reads (4%) | catalogued as rs1258729299; called by muse, mutect2
- DCHS2 | n.5357C>T | RNA (SNP) | VAF 110/405 reads (27%) | called by muse, mutect2, varscan2
